CPTAC case C3L-00001 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/13310f38-a002-437e-8de2-332b0b10d0c0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1954; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Classification of tumor: primary; Age at diagnosis: 61.5 years (22,455 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Prior malignancy: no; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,837 days (5.0 years); Progression or recurrence: no; Days to last follow up: 1,837 days (5.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.7 cm (a second GDC size field records 13.5 cm); Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 8; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 519 days (1.4 years); Disease response: Tumor Free.
- Days to follow up: 714 days (2.0 years); Disease response: Tumor Free.
- Days to follow up: 1,065 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,423 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,837 days (5.0 years); Disease response: Complete Response.
- Days to follow up: 1,837 days (5.0 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 71.6 kg; Height: 180.3 cm; BMI: 22.03; Comorbidities: Sjogren's Syndrome.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00001-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 224 mg; Longest dimension: 37; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00001-21: Section location: Right Upper Lobe; Percent tumor nuclei: 85; Percent necrosis: 1.
- Sample C3L-00001-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 335 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00001-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Time between excision and freezing: 7 minutes; Method of sample procurement: Blood Draw.
